Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5458, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5458-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Report Status: Final

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT

CGA-CZ-5458

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "RIGHT KIDNEY, NEPHRECTOMY":
RENAL CELL CARCINOMA (9.2 cm), clear cell type, with focal spindle cell areas, Fuhrman nuclear grade III (of IV).
The tumor extends through the renal capsule and into the perirenal adipose tissue.
The resection margins are negative for tumor.
No lymphovascular invasion identified.
The ureter, vein, and artery margins are negative for tumor.
AJCC Classification (6th Edition): T3 Nx MX.
The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

NOTE:
Selected slides were reviewed with Dr. [REDACTED] Pathology Service, who concurs.

CLINICAL DATA:

History: None given.
Operation: Right radical nephrectomy.
Operative Findings: None given.
Clinical Diagnosis: Preop: Right kidney mass.

ORGAN/TISSUE SUBMITTED:

A/1. Right kidney to tumor bank.

GROSS DESCRIPTION:

The specimen is received fresh in one part, labeled with the patient's name, unit number, and "#1. Right kidney", and consists of a 755-gram radical nephrectomy specimen including right kidney (17.8 x 10.1 x 7.0 cm), ureter (9.5 x 0.4 cm in diameter), renal vein (0.6 cm in length x 1.0 cm in diameter), renal artery #1 (1.5 x 0.5 cm in diameter), and renal artery #2 (2.3 x 0.4 cm in diameter). A focal hemorrhagic, well encapsulated tan/yellow to tan/red focally cystic mass (9.2 x 8.1 x 7.0 cm) is located in the upper pole. The mass abuts the kidney capsule and is 0.2 cm to the inked margin, 12.0 cm to ureter, 2.2 cm artery #2, 3.3 cm artery #1, and 2.2 cm to the vein margins. There is focus suspicious for extracapsular invasion, however, the renal pelvis does not seem to be invaded. The outer surface is inked black.
Representative sections of the tumor were sent for cytogenetics, electron microscopy, and submitted to the tissue bank. Representative sections of normal cortex were submitted for electron microscopy, immunofluorescence, and tissue bank. Representative sections are submitted for histology.

Micro A1-A2: Tumor, capsule infrarenal fat, 2 frags each, [REDACTED]
Micro A3: Tumor to renal pelvis, 1 frag, [REDACTED]
Micro A4: Tumor and renal parenchyma, 1 frag, [REDACTED]
Micro A5: Ureter, arteries, and vein margin, multi frags, [REDACTED]
Micro A6: Uninvolved renal parenchyma, 1 frag, [REDACTED]
Micro A7: T1 remnant, 1 frag, [REDACTED]
Micro A8: T2 remnant, 1 frag, [REDACTED]
Micro A9: Additional sections of tumor capsule, 2 frags, [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated)

[page 2 of 2]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics

Report Status: Final

Cytogeneticist: [REDACTED]

TCGA-CZ-5458

KARYOTYPE:

T2:45,Y,t(X;3)(p21;q21),+der(X)t(X;3)(p21.2;q21),-3,add(11)(q2?4),
-21[cp10]/46,XY[1]

METAPHASES COUNTED: 11

ANALYZED: 7

SCORED: 4

BANDING: GTG

INTERPRETATION:

Ten of 11 metaphases from specimen labeled T2 contained the clonal aberrations described above. Loss of the short arm of chromosome 3 is a characteristic finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

No metaphases were available from specimen labeled T1.

INDICATION FOR TEST:

? Renal Cell Carcinoma

[REDACTED]

Source: NCI Genomic Data Commons file be1b88fc-1516-4f0a-8293-b5da10b7c97f (TCGA-CZ-5458.110912DE-59B9-4EAD-BD97-CA82D14F4B0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).